Somatic mutation profile of tumor specimen TCGA-CV-6954-01A (aliquot TCGA-CV-6954-01A-11D-1912-08) from TCGA case TCGA-CV-6954, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.0 years (21,557 days).
Specimen TCGA-CV-6954-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6862dcf-bc0a-42c6-8a13-6a7416bc920a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6954-10A (Blood Derived Normal), aliquot TCGA-CV-6954-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5734d2c-638d-4731-a52b-88d2ff0298f7

The open-access MAF lists 133 somatic variants for this specimen: 104 protein-altering or splice-affecting, 26 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 26, Nonsense Mutation 6, Splice Site 4, Frame Shift Del 3, Frame Shift Ins 2, RNA 2, Splice Region 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.2092G>T p.V698L | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.225); catalogued as COSV100205878; called by muse, mutect2
- ACSL4 | c.1938A>T p.E646D (on ENST00000340800 / NM_022977.2; = p.E605D on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100538623; called by muse, mutect2, varscan2
- ADGRE1 | c.2026T>G p.F676V | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99165358; called by muse, mutect2, varscan2
- ARHGAP10 | c.1778C>G p.P593R | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.971); catalogued as rs1230220881, COSV100331301, COSV60599839; called by muse, mutect2, varscan2
- ARHGAP35 | c.1165G>C p.D389H | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.785); catalogued as COSV101351120; called by muse, mutect2, varscan2
- ARNT2 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV100309084, COSV57584367; called by muse, mutect2, varscan2
- ARNT2 | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs144530385, COSV100308811; called by muse, mutect2, varscan2
- ARRDC2 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99716783; called by muse, mutect2, varscan2
- ASPH | c.674A>C p.D225A | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.268); catalogued as COSV100727600; called by muse, mutect2, varscan2
- C12orf4 | c.1594C>G p.L532V | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV99712759; called by muse, mutect2, varscan2
- CACNA1H | c.4637T>C p.V1546A | Missense Mutation (SNP) | VAF 102/286 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100672798; called by muse, varscan2
- CACNG8 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.162); catalogued as rs770734902, COSV99555019; called by muse, mutect2, varscan2
- CARD6 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs749841915, COSV54565169; called by muse, mutect2, varscan2
- CCDC88A | c.4032G>C p.Q1344H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99710532; called by muse, mutect2, varscan2
- CCL23 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs773536611; called by muse, mutect2, varscan2
- CCR2 | c.401T>A p.L134Q | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99432421; called by muse, mutect2
- CD9 | c.324C>G p.I108M | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1229629579, COSV99153002; called by muse, mutect2, varscan2
- CDC42BPG | c.1318C>G p.P440A | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100712089; called by muse, mutect2
- CELF2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.678); catalogued as COSV101011329; called by muse, mutect2, varscan2
- CHD7 | c.8213C>T p.T2738M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs761409446, COSV71109597; ClinVar: uncertain significance; called by muse, varscan2
- CHST12 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 70/136 reads (51%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1054296869, COSV99324516; called by muse, mutect2, varscan2
- CLCA2 | c.1033A>T p.I345F | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as COSV100991565; called by muse, mutect2
- CLDN18 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs141484279; called by muse, mutect2, varscan2
- CLHC1 | c.1364A>T p.Q455L | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV101284898; called by muse, mutect2
- COG4 | c.468G>T p.E156D | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV100091843; called by muse, mutect2, varscan2
- CRYZL1 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV99280986; called by muse, varscan2
- DNAH5 | c.10227G>A p.W3409* | Nonsense Mutation (SNP) | VAF 30/138 reads (22%) | catalogued as COSV99450458; called by muse, mutect2, varscan2
- DYRK1B | c.247_249del p.K83del | In Frame Del (DEL) | VAF 26/110 reads (24%) | catalogued as rs769967128; called by pindel, varscan2
- EPHA5 | c.2372T>C p.L791P | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99899264; called by muse, mutect2, varscan2
- EVC2 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.977); catalogued as COSV100186112; called by muse, mutect2, varscan2
- FAT2 | c.12973C>T p.P4325S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99943097; called by muse, mutect2, varscan2
- FCRL4 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV54866775, COSV99619921; called by muse, mutect2
- FGFR2 | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV60650941; called by muse, mutect2, varscan2
- FNDC1 | c.5399T>C p.L1800P | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99795980; called by muse, mutect2, varscan2
- GRIA4 | c.337T>A p.L113I | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV99231936; called by muse, mutect2, varscan2
- GSDME | c.530A>T p.E177V | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); catalogued as COSV100742351; called by muse, mutect2, varscan2
- H3C6 | c.110A>T p.K37M | Missense Mutation (SNP) | VAF 94/154 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.357); catalogued as COSV100839028; called by muse, mutect2, varscan2
- HCN1 | c.2375C>T p.S792L | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs140758934, COSV57497778; called by muse, mutect2
- HPDL | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV100588049, COSV58343602; called by muse, mutect2, varscan2
- HRH2 | c.472T>A p.W158R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99199667; called by muse, mutect2, varscan2
- HS2ST1 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV63349000; called by muse, mutect2
- HSPA1L | c.1241C>A p.A414D | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.405); catalogued as COSV100989402; called by muse, mutect2
- KCNT2 | c.2954A>T p.D985V | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV99654205; called by muse, mutect2, varscan2
- KMT2A | c.10745+1G>T p.X3582_splice | Splice Site (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100628981; called by muse, mutect2
- KRTAP4-12 | c.35A>G p.D12G | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV101224279; called by muse, mutect2, varscan2
- LEPR | c.1733G>T p.G578V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs1163084980, COSV100756589, COSV60762572; called by muse, mutect2, varscan2
- LRRC32 | c.1478T>A p.L493* | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99476995; called by muse, mutect2, varscan2
- MAN2A2 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.716); catalogued as COSV100847882; called by muse, mutect2, varscan2
- MAP1A | c.5886G>C p.E1962D | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs1288689640, COSV100288721; called by muse, mutect2, varscan2
- MIA3 | c.1908T>A p.D636E | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.067); catalogued as COSV100719460; called by muse, mutect2, varscan2
- NCAPD3 | c.4054A>G p.I1352V | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.082); catalogued as COSV101592168; called by muse, mutect2, varscan2
- NLGN4Y | c.754G>T p.G252C | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100196866; called by muse, mutect2
- NOP56 | c.838A>G p.S280G | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV100250140; called by muse, mutect2, varscan2
- NUP133 | c.322A>G p.N108D | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV99772991; called by muse, mutect2
- OR13D1 | c.829T>A p.S277T | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100598694, COSV59513850; called by muse, mutect2
- OR8K5 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | catalogued as rs147577134, COSV57889485; called by muse, mutect2, varscan2
- PKHD1L1 | c.10349A>T p.K3450M | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV101006226; called by muse, mutect2, varscan2
- PLG | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51981343, COSV99804735; called by muse, mutect2
- PPP2R5C | c.1352C>T p.T451I | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs1451132454, COSV100159562; called by muse, mutect2, varscan2
- PZP | c.2789-1G>A p.X930_splice | Splice Site (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99738074; called by muse, mutect2, varscan2
- RANBP2 | c.6955C>G p.L2319V | Missense Mutation (SNP) | VAF 114/346 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.867); catalogued as rs759284450, COSV99312253; called by muse, mutect2, varscan2
- RASA2 | c.2329+1G>T p.X777_splice | Splice Site (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99656226; called by muse, mutect2
- RBM26 | c.2863C>G p.L955V (on ENST00000438737 / NM_001366735.2; = p.L928V on NM_022118.5) | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs1334268860, COSV99936220; called by muse, mutect2, varscan2
- RESF1 | c.53A>T p.K18I | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100440386; called by muse, mutect2, varscan2
- RHOBTB1 | c.443A>G p.D148G | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV100558505; called by muse, mutect2, varscan2
- ROBO4 | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs374471211; called by muse, mutect2
- ROR1 | c.1439G>A p.G480D | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100935280; called by muse, mutect2
- RPAP1 | c.2930C>G p.A977G | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV100427161; called by muse, mutect2
- RTN4R | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as rs1221580511, COSV99245073; called by muse, mutect2, varscan2
- SCN11A | c.5125G>C p.E1709Q | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100181693; called by muse, mutect2, varscan2
- SEMA3A | c.1799A>T p.K600M | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs535486545, COSV99546881; called by muse, mutect2, varscan2
- SERPINB11 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1428809944, COSV101236249; called by muse, mutect2, varscan2
- SLC12A1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1424125008, COSV100372387; called by muse, mutect2, varscan2
- SLC5A7 | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50897890; called by muse, mutect2, varscan2
- SPATC1 | c.1568C>A p.A523E | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as rs782379736, COSV101085015, COSV66300143; called by muse, mutect2, varscan2
- SPINK5 | c.3122G>A p.R1041H | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as rs1412152696, COSV99806847; called by muse, mutect2, varscan2
- SRD5A2 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV99252424; called by muse, mutect2, varscan2
- STAG1 | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV99365695; called by muse, mutect2
- SYNC | c.1355A>G p.Y452C | Missense Mutation (SNP) | VAF 150/349 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201938976, COSV65131259; called by muse, mutect2, varscan2
- SYNJ1 | c.532T>A p.L178I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100449353; called by muse, mutect2, varscan2
- TAP1 | c.913G>A p.G305S | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.068); catalogued as COSV100841223; called by muse, mutect2
- TCFL5 | c.953G>C p.R318T | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.977); catalogued as COSV99415904; called by muse, mutect2
- TGFBR2 | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 33/62 reads (53%) | catalogued as COSV55445679, COSV55458087, COSV55461455; called by muse, mutect2, varscan2
- TIPIN | c.13C>T p.Q5* | Nonsense Mutation (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99972395; called by muse, mutect2, varscan2
- TMPRSS13 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.013); catalogued as rs762493127, COSV101471449; called by muse, mutect2, varscan2
- TNRC6A | c.2431A>G p.T811A | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs772294324, COSV100170088; called by muse, mutect2, varscan2
- TPRG1L | c.512G>T p.S171I | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.69); catalogued as COSV99573336; called by muse, mutect2
- TSNAXIP1 | c.1247C>A p.T416K | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99535143; called by muse, mutect2, varscan2
- TTN | c.13356G>C p.E4452D (on ENST00000591111; = p.E4406D on NM_003319.4) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | PolyPhen probably damaging (0.99); catalogued as COSV100615940; called by muse, mutect2, varscan2
- UMOD | c.1798A>G p.N600D | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.029); catalogued as COSV100208413, COSV56773465; called by muse, mutect2, varscan2
- USP40 | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV99296523; called by muse, mutect2, varscan2
- VPS13B | c.3953C>G p.T1318S | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100662203, COSV62159516; called by muse, mutect2
- WASHC5 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs565980279, COSV100572855; called by muse, mutect2, varscan2
- ZBTB11 | c.2058G>C p.K686N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144559723; called by muse, mutect2, varscan2
- ZFYVE26 | c.1018-2A>G p.X340_splice | Splice Site (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100720465; called by muse, mutect2
- ZMAT1 | c.1384G>A p.V462M | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as rs753565056, COSV100858828; called by muse, mutect2, varscan2
- ZNF318 | c.6710A>C p.K2237T | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.91); catalogued as COSV100546223; called by muse, mutect2
- ZPLD1 | c.-8G>T | Splice Region (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100082850; called by muse, mutect2, varscan2
- DBR1 | c.164_165insAC p.P56Rfs*53 | Frame Shift Ins (INS) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- ITSN2 | c.2057dup p.K687Efs*5 | Frame Shift Ins (INS) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- RALGPS1 | c.1141del p.R381Efs*6 | Frame Shift Del (DEL) | VAF 15/113 reads (13%) | called by mutect2, pindel, varscan2
- TP53 | c.415_451del p.K139Pfs*19 | Frame Shift Del (DEL) | VAF 33/57 reads (58%) | called by mutect2, pindel
- TRGC2 | c.383T>G p.V128G | Missense Mutation (SNP) | VAF 9/247 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.138); called by muse, mutect2
- ZNF782 | c.1058del p.F353Sfs*9 | Frame Shift Del (DEL) | VAF 83/171 reads (49%) | called by mutect2, pindel, varscan2
- AARS2 | c.1890G>A p.A630= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs757968286, COSV99771483; called by muse, mutect2, varscan2
- ADGRV1 | c.10638T>A p.P3546= | Silent (SNP) | VAF 11/320 reads (3%) | catalogued as COSV101316073; called by muse, mutect2
- ATP1A3 | c.3012C>T p.Y1004= (on ENST00000545399 / NM_001256214.2; = p.Y991= on NM_152296.5) | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as rs372919447; called by muse, mutect2, varscan2
- DIS3L2 | c.1566C>T p.S522= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs374299868; ClinVar: likely benign; called by muse, mutect2, varscan2
- DLST | c.1350C>G p.L450= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as COSV53168185; called by muse, mutect2, varscan2
- EPHA5 | c.2541A>T p.P847= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV56648755, COSV99899262; called by muse, mutect2, varscan2
- FAM162B | c.229C>T p.L77= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as rs1031144647, COSV63920666; called by muse, mutect2, varscan2
- FAM83A | c.798G>C p.V266= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99414308; called by muse, mutect2, varscan2
- HOXD12 | c.6T>C p.C2= | Silent (SNP) | VAF 83/175 reads (47%) | catalogued as COSV101184282; called by muse, mutect2, varscan2
- LPAR1 | c.486G>A p.R162= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV62687277; called by muse, mutect2, varscan2
- NFATC2 | c.708G>A p.S236= | Silent (SNP) | VAF 28/275 reads (10%) | catalogued as COSV101044188; called by muse, mutect2
- NOD2 | c.510C>T p.I170= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs1361785600, COSV56054721; called by muse, mutect2, varscan2
- OR51B2 | c.627T>C p.C209= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100173315, COSV100173394; called by muse, mutect2, varscan2
- PCDHB7 | c.1452C>T p.A484= | Silent (SNP) | VAF 29/145 reads (20%) | catalogued as rs149570059; called by muse, mutect2, varscan2
- PRKD1 | c.2652G>T p.L884= | Silent (SNP) | VAF 35/142 reads (25%) | catalogued as COSV100120507; called by muse, mutect2, varscan2
- RANBP10 | c.501C>T p.D167= | Silent (SNP) | VAF 19/106 reads (18%) | catalogued as rs373521031; called by muse, mutect2, varscan2
- SLC17A1 | c.171C>T p.P57= | Silent (SNP) | VAF 64/250 reads (26%) | catalogued as rs927789287, COSV99765811; called by muse, mutect2, varscan2
- SMARCA1 | c.1062C>T p.L354= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as COSV100946564, COSV64411091; called by muse, mutect2, varscan2
- TBX19 | c.735C>A p.G245= | Silent (SNP) | VAF 19/99 reads (19%) | catalogued as COSV100892361; called by muse, mutect2, varscan2
- THSD7A | c.1344C>T p.R448= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs776774107, COSV101448556; called by muse, mutect2, varscan2
- TLR1 | c.246G>A p.Q82= | Silent (SNP) | VAF 8/204 reads (4%) | catalogued as rs1281021348, COSV100458535; called by muse, mutect2
- TMEM120B | c.933C>T p.L311= | Silent (SNP) | VAF 40/104 reads (38%) | catalogued as rs1351855804, COSV99932288; called by muse, mutect2, varscan2
- UTP20 | c.3993A>G p.K1331= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV55373555; called by muse, mutect2, varscan2
- WDR72 | c.999A>G p.K333= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100854563; called by muse, mutect2, varscan2
- WFDC3 | c.288A>G p.P96= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as COSV99714595; called by muse, mutect2, varscan2
- XDH | c.1332A>T p.P444= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV101052221; called by muse, mutect2
- AL109984.1 | n.186+5014G>A | Intron (SNP) | VAF 87/215 reads (40%) | catalogued as rs1317760376, COSV100801616; called by muse, mutect2, varscan2
- ISCA1P1 | n.62C>G | RNA (SNP) | VAF 25/42 reads (60%) | called by muse, mutect2, varscan2
- XIST | n.8926C>A | RNA (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
